Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1DP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1DP-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Adenocarcinoma, endometrioid, NOS 8380/3

Site Code: Endometrium C54.1

TSS Name/##:

1/12

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries
- 2: SP: Portion of omentum
- 3: SP: Right common iliac lymph node
- 4: SP: Right para-aortic lymph node
- 5: SP: Left para-aortic lymph node
- 6: SP: Right external iliac lymph node
- 7: SP: Right obturator lymph node
- 8: SP: Right internal iliac lymph node
- 9: SP: Left external iliac lymph node
- 10: SP: Left hypogastric lymph node
- 11: SP: Left obturator lymph node

AMENDED DIAGNOSIS:

- 1) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE II (6-50% SOLID GROWTH), NUCLEAR GRADE 2.
- THE TUMOR INVADES TO LESS THAN OR EQUAL TO HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 1.3 CM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 2.8 CM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- CERVIX: BENIGN SQUAMOUS MUCOSA.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY(IES): ATROPHY.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY(IES): ADENOMYOSIS AND LEIOMYOMA(S).
- ALL ADNEKAE ARE UNREMARKABLE.
- 2) OMENTUM; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- 3) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

** Continued on next page **

[page 2 of 2]
TSS Name/##

Page 2 of 7

- 4) LYMPH NODE, RIGHT PARA-AORTIC-AORTIC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 5) LYMPH NODE, LEFT PARA-AORTIC-AORTIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 6) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 7) LYMPH NODE, RIGHT OBTURATOR; EXCISION: - TWO BENIGN LYMPH NODES
(0/2).
- 8) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION: - TWO BENIGN LYMPH
NODES (0/2).
- 9) LYMPH NODE, LEFT EXTERNAL ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 10) LYMPH NODE, LEFT HYPOGASTRIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- ONE LYMPH NODE HAS FOCAL ENDOSALPINGIOSIS.
- 11) LYMPH NODE, LEFT OBTURATOR; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 41e45886-4b0f-45cb-ba7a-a0284871c0e4 (TCGA-AP-A1DP.20EEB047-0185-4B65-9A6A-43D6C97307C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).